Somatic mutation profile of tumor specimen MP2PRT-PAUBKT-TMP1-A (aliquot MP2PRT-PAUBKT-TMP1-A-1-0-D-A83O-36) from MP2PRT case MP2PRT-PAUBKT, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.3 years (1,561 days).
Specimen MP2PRT-PAUBKT-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0ba730d2-f254-45e4-b87c-eaba41564978.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUBKT-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUBKT-NB1-A-1-0-D-A83O-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8e61c872-1e39-4637-98ea-cbc470513a8d

The open-access MAF lists 15 somatic variants for this specimen: 13 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Nonsense Mutation 3, Silent 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AHCYL2 | c.592C>T p.R198* | Nonsense Mutation (SNP) | VAF 76/303 reads (25%) | catalogued as rs1447851387; called by muse, mutect2, varscan2
- GABRA1 | c.1069G>A p.V357I | Missense Mutation (SNP) | VAF 80/173 reads (46%) | SIFT tolerated (0.2); PolyPhen benign (0.275); catalogued as COSV50099299; called by muse, mutect2, varscan2
- LRP1B | c.11362G>A p.G3788R | Missense Mutation (SNP) | VAF 32/380 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.958); catalogued as rs199649226, COSV67221081, COSV67275670; called by muse, mutect2
- LY75 | c.212C>T p.S71F | Missense Mutation (SNP) | VAF 107/440 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1207981062; called by muse, mutect2, varscan2
- AL592490.1 | c.2678T>G p.L893R | Missense Mutation (SNP) | VAF 93/369 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- COBLL1 | c.1870G>A p.G624S (on ENST00000392717; = p.G586S on NM_014900.5) | Missense Mutation (SNP) | VAF 94/196 reads (48%) | SIFT tolerated (0.24); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DDX50 | c.538C>T p.Q180* | Nonsense Mutation (SNP) | VAF 75/413 reads (18%) | called by muse, mutect2, varscan2
- EEF1AKNMT | c.86T>G p.F29C | Missense Mutation (SNP) | VAF 81/366 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- IGKV1D-16 | chr2:90100737 CTCC>TCCTG | Missense Mutation (INS) | VAF 65/104 reads (63%) | called by pindel, varscan2*
- IGKV2D-24 | chr2:90005629 del TCA | Missense Mutation (DEL) | VAF 14/124 reads (11%) | called by pindel*, varscan2
- NDST4 | c.2010C>A p.Y670* | Nonsense Mutation (SNP) | VAF 26/388 reads (7%) | called by muse, mutect2
- NKX6-2 | c.354G>T p.W118C | Missense Mutation (SNP) | VAF 52/558 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- ZWINT | c.518A>T p.E173V | Missense Mutation (SNP) | VAF 59/286 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- FBXO41 | c.1434C>T p.S478= | Silent (SNP) | VAF 106/448 reads (24%) | catalogued as rs773663984; called by muse, mutect2, varscan2
- MRI1 | c.548-171G>C | Intron (SNP) | VAF 54/262 reads (21%) | catalogued as COSV50005765; called by mutect2, varscan2
